Somatic mutation profile of tumor specimen MMRF_1880_2_BM_CD138pos (aliquot MMRF_1880_2_BM_CD138pos_T1_KBS5U_L07221) from MMRF case MMRF_1880, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.5 years (24,288 days).
Specimen MMRF_1880_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6ca34ab7-8ba2-4b00-8380-e6b2b1e2369b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1880_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1880_1_PB_Whole_C9_KBS5U_L07222; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bed6dc2b-aa60-44dc-93d6-386413df7af0

The open-access MAF lists 94 somatic variants for this specimen: 48 protein-altering or splice-affecting, 7 silent, 39 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, 3'UTR 21, Intron 12, Silent 7, Nonsense Mutation 4, RNA 3, Frame Shift Del 2, 5'UTR 2, Splice Region 2, Frame Shift Ins 1, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 9/74 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- PDE6A | c.769C>T p.R257* | Nonsense Mutation (SNP) | VAF 11/155 reads (7%) | catalogued as rs146591309, CM066961; ClinVar: pathogenic; called by muse, mutect2
- ACE | c.3135C>T p.D1045= | Splice Region (SNP) | VAF 5/33 reads (15%) | catalogued as rs200011052; called by muse, mutect2, varscan2
- ACTN2 | c.2201C>T p.T734I | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs886046207, COSV63978677; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CARD10 | c.2971G>A p.A991T | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs769913613; called by muse, mutect2, varscan2
- CDK13 | c.4016T>A p.F1339Y | Missense Mutation (SNP) | VAF 57/225 reads (25%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.931); catalogued as rs1246652640; called by muse, mutect2, varscan2
- CYP4F22 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761963345, COSV54107667; called by muse, mutect2, varscan2
- DACT1 | c.1940C>T p.A647V | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0.012); catalogued as rs1478003295; called by muse, mutect2
- EPPK1 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs782397354, COSV73262380; called by muse, mutect2
- GNAT3 | c.239C>A p.S80Y | Missense Mutation (SNP) | VAF 54/187 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1355656169; called by muse, mutect2, varscan2
- IGHD3-9 | c.5T>C p.L2S | Missense Mutation (SNP) | VAF 8/10 reads (80%) | catalogued as rs369734836; called by muse, mutect2
- IGHV1-69 | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 70/168 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs782425771; called by muse, mutect2, varscan2
- IGHV2-70 | c.262C>G p.L88V | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.701); catalogued as rs376644103; called by muse, varscan2
- IGHV2-70 | c.220T>C p.W74R | Missense Mutation (SNP) | VAF 46/86 reads (53%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.688); catalogued as rs375052259; called by muse, varscan2
- IGLV3-1 | c.47-2A>G p.X16_splice | Splice Site (SNP) | VAF 92/148 reads (62%) | catalogued as rs181922188; called by muse, varscan2
- IGLV3-1 | c.245G>C p.G82A | Missense Mutation (SNP) | VAF 81/136 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as rs373575867; called by muse, varscan2
- IGLV3-1 | c.311A>G p.Y104C | Missense Mutation (SNP) | VAF 102/157 reads (65%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); catalogued as rs142180628; called by muse, varscan2
- LCP2 | c.1517G>A p.R506K | Missense Mutation (SNP) | VAF 125/438 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV50469362; called by muse, mutect2, varscan2
- MYO10 | c.2863C>T p.R955W | Missense Mutation (SNP) | VAF 106/181 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.639); catalogued as rs770160016; called by muse, mutect2, varscan2
- NUAK1 | c.1831C>T p.Q611* | Nonsense Mutation (SNP) | VAF 7/101 reads (7%) | catalogued as COSV54604497; called by muse, mutect2
- PCDHAC2 | c.1193G>A p.R398Q | Missense Mutation (SNP) | VAF 21/277 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs782716187, COSV53842989; called by muse, mutect2
- PTPRF | c.4479del p.F1493Lfs*47 | Frame Shift Del (DEL) | VAF 37/93 reads (40%) | catalogued as COSV63448605; called by mutect2, pindel, varscan2
- RINT1 | c.2090A>G p.N697S | Missense Mutation (SNP) | VAF 52/190 reads (27%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.714); catalogued as rs777493133; called by muse, mutect2, varscan2
- SI | c.475C>T p.R159W | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as rs201105530, COSV52281341, COSV52303550; called by muse, mutect2, varscan2
- SLC26A4 | c.768G>A p.T256= | Splice Region (SNP) | VAF 6/23 reads (26%) | catalogued as rs552050976, CD1213291; called by muse, varscan2
- SPTBN1 | c.22G>A p.D8N | Missense Mutation (SNP) | VAF 15/247 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.834); catalogued as COSV100777180; called by muse, mutect2
- ADGRA3 | c.2770G>T p.A924S | Missense Mutation (SNP) | VAF 55/131 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- ARHGAP35 | c.2399T>A p.L800H | Missense Mutation (SNP) | VAF 19/354 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- B4GALNT1 | c.653G>A p.R218K | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT tolerated (0.95); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- BICRAL | c.2312T>C p.L771P | Missense Mutation (SNP) | VAF 18/241 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- BSN | c.1920G>T p.R640S | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2
- COL6A5 | c.2893G>T p.A965S | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CYFIP1 | c.2428A>T p.K810* | Nonsense Mutation (SNP) | VAF 75/313 reads (24%) | called by muse, mutect2, varscan2
- DKC1 | c.370C>G p.L124V | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- DNAH9 | c.12734T>C p.V4245A | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0.012); called by muse, mutect2
- ERCC6L | c.793_796del p.Q265Nfs*18 | Frame Shift Del (DEL) | VAF 14/136 reads (10%) | called by mutect2, pindel
- FAM160A2 | c.1030G>T p.V344L | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- HIVEP3 | c.1989dup p.Y664Ifs*23 | Frame Shift Ins (INS) | VAF 50/156 reads (32%) | called by mutect2, pindel, varscan2
- IGHV2-70D | c.310A>G p.T104A | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); called by mutect2, varscan2
- MAGI3 | c.4041A>T p.E1347D | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.043); called by muse, mutect2
- MBD4 | c.606A>C p.R202S | Missense Mutation (SNP) | VAF 159/267 reads (60%) | SIFT tolerated (0.19); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MYBPH | c.1107A>T p.K369N | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- MYH3 | c.1129G>C p.D377H | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- MYH8 | c.2758G>A p.A920T | Missense Mutation (SNP) | VAF 88/233 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- OR5D18 | c.601T>C p.F201L | Missense Mutation (SNP) | VAF 12/312 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.107); called by muse, mutect2
- PCDHA11 | c.1473C>G p.Y491* | Nonsense Mutation (SNP) | VAF 6/73 reads (8%) | called by muse, mutect2
- PSMD13 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0.033); called by muse, mutect2
- WDR45 | c.770A>G p.D257G (on ENST00000376372 / NM_001029896.2; = p.D258G on NM_007075.3) | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- NFATC1 | c.1371A>G p.G457= | Silent (SNP) | VAF 32/66 reads (48%) | called by muse, mutect2, varscan2
- NTN1 | c.639C>T p.L213= | Silent (SNP) | VAF 6/79 reads (8%) | called by muse, mutect2
- PDCD7 | c.619C>T p.L207= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as rs1369199154; called by muse, mutect2
- RERE | c.3348G>A p.P1116= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as rs754887260; called by muse, mutect2, varscan2
- RTL3 | c.1050G>A p.L350= | Silent (SNP) | VAF 6/92 reads (7%) | called by muse, mutect2
- SEMA4G | c.411C>T p.A137= | Silent (SNP) | VAF 90/192 reads (47%) | called by muse, mutect2, varscan2
- SURF6 | c.588C>T p.P196= | Silent (SNP) | VAF 40/151 reads (26%) | catalogued as rs375054880; called by muse, mutect2, varscan2
- ADCY1 | c.*443G>A | 3'UTR (SNP) | VAF 5/77 reads (6%) | catalogued as rs1032526656; called by muse, mutect2
- ALS2CL | c.2685-80G>A | Intron (SNP) | VAF 48/184 reads (26%) | catalogued as rs1453030249; called by muse, mutect2, varscan2
- AMACR | c.-8G>A | 5'UTR (SNP) | VAF 19/71 reads (27%) | called by muse, mutect2, varscan2
- ANTXR2 | c.*5404C>G | 3'UTR (SNP) | VAF 21/46 reads (46%) | called by muse, mutect2, varscan2
- C5orf60 | n.529T>C | RNA (SNP) | VAF 4/14 reads (29%) | catalogued as rs867509473; called by mutect2, varscan2
- C6orf52 | c.317-1149G>A | Intron (SNP) | VAF 3/9 reads (33%) | called by muse, mutect2
- CDS1 | c.*1789dup | 3'UTR (INS) | VAF 29/83 reads (35%) | catalogued as rs938607405; called by mutect2, varscan2
- CHRNB2 | c.*3866G>A | 3'UTR (SNP) | VAF 15/94 reads (16%) | called by muse, mutect2, varscan2
- CLDND2 | c.431-88A>G | Intron (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
- CNTNAP2 | c.*933A>C | 3'UTR (SNP) | VAF 21/87 reads (24%) | called by muse, mutect2, varscan2
- CSF1R | c.2655-36G>A | Intron (SNP) | VAF 32/48 reads (67%) | called by muse, mutect2, varscan2
- DAPK2 | c.858+2019T>C | Intron (SNP) | VAF 37/179 reads (21%) | called by muse, mutect2, varscan2
- DNAI1 | c.262-1214A>G | Intron (SNP) | VAF 38/115 reads (33%) | called by muse, mutect2, varscan2
- EIF5AL1 | c.*741C>A | 3'UTR (SNP) | VAF 6/113 reads (5%) | called by muse, mutect2
- HAPLN1 | c.*2467A>C | 3'UTR (SNP) | VAF 23/69 reads (33%) | called by muse, mutect2, varscan2
- HID1 | c.388-61C>T | Intron (SNP) | VAF 24/58 reads (41%) | called by muse, mutect2, varscan2
- IDE | c.*2251G>C | 3'UTR (SNP) | VAF 16/52 reads (31%) | called by muse, mutect2, varscan2
- ISM2 | c.*875dup | 3'UTR (INS) | VAF 36/118 reads (31%) | called by mutect2, pindel, varscan2
- KIAA1210 | c.*1749G>A | 3'UTR (SNP) | VAF 7/59 reads (12%) | catalogued as rs998919097; called by mutect2, varscan2
- LTB | c.162+61G>A | Intron (SNP) | VAF 29/71 reads (41%) | catalogued as rs932462715; called by muse, mutect2, varscan2
- MIR409 | n.32T>G | RNA (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2
- MPST | c.595+38G>T | Intron (SNP) | VAF 8/101 reads (8%) | catalogued as rs1203634410; called by muse, mutect2
- NPM2 | c.567-75G>A | Intron (SNP) | VAF 6/78 reads (8%) | catalogued as COSV57076580; called by muse, mutect2
- PDE10A | c.*4399A>G | 3'UTR (SNP) | VAF 23/70 reads (33%) | called by muse, mutect2, varscan2
- PHF20L1 | c.*721A>G | 3'UTR (SNP) | VAF 23/62 reads (37%) | called by muse, mutect2, varscan2
- PLEKHH2 | c.*1249C>T | 3'UTR (SNP) | VAF 10/31 reads (32%) | called by muse, mutect2
- PNKD | c.*673G>A | 3'UTR (SNP) | VAF 7/117 reads (6%) | called by muse, mutect2
- RAG1 | c.*258C>G | 3'UTR (SNP) | VAF 10/89 reads (11%) | called by muse, mutect2, varscan2
- RBM46 | c.1403-639G>A | Intron (SNP) | VAF 45/105 reads (43%) | called by muse, mutect2, varscan2
- RRP1 | c.*1061A>G | 3'UTR (SNP) | VAF 33/130 reads (25%) | catalogued as rs754803446; called by muse, mutect2, varscan2
- RXRA | c.*173G>C | 3'UTR (SNP) | VAF 8/116 reads (7%) | called by muse, mutect2
- STARD4 | c.155+22T>G | Intron (SNP) | VAF 8/28 reads (29%) | called by muse, mutect2
- TBC1D4 | c.-7G>T | 5'UTR (SNP) | VAF 6/53 reads (11%) | catalogued as rs763844575; called by muse, mutect2, varscan2
- TMPRSS11E | c.*689A>G | 3'UTR (SNP) | VAF 35/92 reads (38%) | catalogued as rs1377562056; called by muse, mutect2, varscan2
- TOR1AIP1 | c.*589A>G | 3'UTR (SNP) | VAF 57/128 reads (45%) | called by muse, mutect2, varscan2
- TRIM60P14 | n.611T>C | RNA (SNP) | VAF 3/15 reads (20%) | catalogued as rs56056003; called by muse, mutect2
- UBL4A | c.*1129C>A | 3'UTR (SNP) | VAF 60/140 reads (43%) | called by muse, mutect2, varscan2
- UTP23 | c.*131T>G | 3'UTR (SNP) | VAF 5/130 reads (4%) | called by muse, mutect2
- UTS2B | chr3:191264855 T>A | 3'Flank (SNP) | VAF 25/98 reads (26%) | called by muse, mutect2, varscan2
